Gene-level copy-number profile of tumor specimen C3L-03965-02 from CPTAC case C3L-03965, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 54.1 years (19,760 days).
Specimen C3L-03965-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e419d66-ba1b-45f7-a3dc-ce011ab596ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03965-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/634720ef-896f-46fa-80f4-d183a4adddab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 366; copy number 1: 4,387; copy number 2: 21,266; copy number 3: 21,609; copy number 4: 7,844; copy number 5: 1,892; copy number 6: 415; copy number 7: 584; copy number 8: 86; copy number 9: 154; copy number 10: 95; copy number 11: 94; copy number 12: 5; copy number 13: 45; copy number 14: 36; copy number 15: 7; copy number 16: 20.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,290,513–149,290,762, 1 gene (within-gene range 0–4): 7SK.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr15:61,181,249–62,954,124, 34 genes (within-gene range 0–1): AC012404.1, AC012404.2, AC107905.1, AC104574.2, AC104574.1, AC018618.1, AC018618.2, LINC02349, AC009554.1, VPS13C, AC009554.2, AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1, AC103740.2, AC079328.1.
- chr15:63,870,930–64,775,589, 28 genes: MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB, CSNK1G1, AC087632.2, AC087632.1, PCLAF, TRIP4, Y_RNA, ZNF609, AC091231.1, GAPDHP61, AC090543.2, AC090543.1, Y_RNA, RNU6-549P, OAZ2, AC100830.3, AC100830.2, AC100830.1, RBPMS2, MIR1272.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–3): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,126 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:180,967,248–181,930,738, 15 genes, copy number 7–14: UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2.
- chr2:214,241,676–214,684,246, 4 genes, copy number 7 (within-gene range 6–10): AC068051.1, RPL5P8, VWC2L, VWC2L-IT1.
- chr3:100,185,687–100,456,319, 7 genes, copy number 7: TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1.
- chr3:173,153,737–190,322,446, 296 genes, copy number 7–13 (broad region; genes not listed).
- chr8:122,485,194–122,733,804, 1 gene, copy number 7 (within-gene range 4–7): LINC01151.
- chr8:122,671,291–124,728,473, 59 genes, copy number 7: AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr8:126,556,323–131,144,948, 55 genes, copy number 7–13 (within-gene range 5–13): PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr8:131,712,512–133,302,022, 20 genes, copy number 9: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1.
- chr8:137,424,904–137,425,021, 1 gene, copy number 7: ZYXP1.
- chr9:61,190,003–61,231,863, 5 genes, copy number 12: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1.
- chr12:17,383,352–18,320,107, 6 genes, copy number 9 (within-gene range 5–9): PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, Y_RNA, RERGL.
- chr12:20,695,332–25,250,936, 67 genes, copy number 7–16 (broad region; genes not listed).
- chr12:30,169,881–32,383,633, 66 genes, copy number 9–15 (within-gene range 5–15) (broad region; genes not listed).
- chr14:22,003,106–22,513,998, 76 genes, copy number 8 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr18:11,666,456–12,076,654, 20 genes, copy number 7–8: AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2.
- chr19:11,466,240–18,791,305, 427 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
